Somatic mutation profile of tumor specimen TCGA-AX-A0IU-01A (aliquot TCGA-AX-A0IU-01A-11D-A10B-09) from TCGA case TCGA-AX-A0IU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.6 years (29,063 days).
Specimen TCGA-AX-A0IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 952167dc-d380-4261-adea-259404b2bb6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A0IU-10A (Blood Derived Normal), aliquot TCGA-AX-A0IU-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b49ba6-c388-4b4a-a86e-4b012da7201a

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Frame Shift Del 2, 3'Flank 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, Translation Start Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAA10 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1557107957, COSV64169364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHCTF1 | c.2998G>T p.V1000L (on ENST00000366508; = p.V974L on NM_015446.5) | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV58245946; called by muse, mutect2, varscan2
- ANKMY1 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56030259; called by muse, mutect2, varscan2
- CD47 | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV62526662; called by muse, mutect2
- CLMN | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54179050; called by muse, mutect2, varscan2
- CSMD3 | c.6173C>A p.P2058H (on ENST00000297405 / NM_001363185.1; = p.P1954H on NM_052900.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52105504; called by muse, mutect2, varscan2
- DUSP29 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555154041, COSV58300017; called by muse, mutect2, varscan2
- EFHC2 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV101375434, COSV69552768; called by muse, varscan2
- EPHX2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs758386893, COSV66843935; called by muse, mutect2, varscan2
- FBXW7 | c.985+1del p.X329_splice (on ENST00000281708 / NM_001349798.2; = p.X249_splice on NM_018315.5) | Splice Site (DEL) | VAF 38/100 reads (38%) | catalogued as COSV55946257; called by mutect2, pindel, varscan2
- GATA1 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64961513; called by muse, mutect2, varscan2
- HSPA14 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.294); catalogued as COSV65683965; called by muse, mutect2
- ITPR1 | c.5257C>G p.R1753G (on ENST00000354582; = p.R1698G on NM_002222.7) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs750361124, COSV56968801; called by muse, mutect2, varscan2
- KDM3A | c.3205A>T p.I1069F | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57218036; called by muse, mutect2
- KLHL18 | c.1430G>A p.S477N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV51744063; called by muse, mutect2, varscan2
- LAMP5 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.833); catalogued as rs1458514359, COSV55715120; called by muse, mutect2, varscan2
- LGALS1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs111700736, COSV53221794; called by muse, mutect2
- LRP1B | c.4840G>A p.D1614N | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs762458785, COSV67183175, COSV67187424; called by muse, mutect2
- MITF | c.278A>C p.Q93P | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV58879888; called by muse, mutect2, varscan2
- MPG | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.811); catalogued as COSV54737360; called by mutect2, varscan2
- NAA30 | c.999T>A p.Y333* | Nonsense Mutation (SNP) | VAF 50/154 reads (32%) | catalogued as COSV53648014; called by muse, mutect2, varscan2
- NBAS | c.5111A>T p.H1704L | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV55712865; called by muse, mutect2
- NEB | c.6730G>T p.D2244Y | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV50812182; called by muse, mutect2, varscan2
- NELL1 | c.1673T>C p.I558T | Missense Mutation (SNP) | VAF 103/201 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs569981136, COSV54239798; called by muse, mutect2, varscan2
- OR2T6 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 124/215 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs770068217, COSV100861630, COSV63215725; called by muse, mutect2, varscan2
- PKD1L1 | c.8300C>T p.T2767I | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV51841329; called by muse, mutect2, varscan2
- PLXNB3 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs782554732, COSV62795465, COSV62803678; called by muse, mutect2, varscan2
- PTN | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV61963366; called by muse, mutect2, varscan2
- RBM25 | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56198580; called by muse, mutect2, varscan2
- RPTN | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 297/755 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV60166305; called by muse, mutect2, varscan2
- RS1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.38); catalogued as CM161473, COSV66105862; called by muse, mutect2, varscan2
- SLC25A14 | c.726C>A p.S242R | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54416924; called by muse, mutect2
- TMEM132D | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.23); catalogued as COSV70594177; called by muse, mutect2, varscan2
- TMEM168 | c.1683C>A p.D561E | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.306); catalogued as COSV57179353; called by muse, mutect2, varscan2
- TP53 | c.831_832dup p.P278Lfs*68 | Frame Shift Ins (INS) | VAF 29/64 reads (45%) | catalogued as COSV99366293; called by mutect2, pindel, varscan2
- WNT5A | c.927C>G p.C309W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52836178, COSV52838417; called by muse, mutect2, varscan2
- ZFYVE16 | c.3461T>G p.F1154C | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62014265; called by muse, mutect2, varscan2
- ZNF470 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57967626; called by muse, mutect2
- ZSWIM8 | c.4135C>T p.R1379W (on ENST00000605216 / NM_001242487.2; = p.R1384W on NM_015037.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760743925, COSV55212813; called by muse, mutect2, varscan2
- RASA1 | c.898del p.S300Vfs*3 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- RASA1 | c.1533del p.K511Nfs*9 | Frame Shift Del (DEL) | VAF 61/160 reads (38%) | called by mutect2, pindel, varscan2
- ALG10 | c.282G>A p.G94= | Silent (SNP) | VAF 49/444 reads (11%) | catalogued as COSV56791722; called by muse, mutect2, varscan2
- ARID5B | c.1851C>T p.P617= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs765232046, COSV54414525, COSV54417117; called by muse, mutect2, varscan2
- AXL | c.819G>A p.A273= | Silent (SNP) | VAF 62/116 reads (53%) | catalogued as rs61737383, COSV56563798; called by muse, mutect2, varscan2
- CCNA1 | c.462G>A p.E154= | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as COSV55219950; called by muse, mutect2
- EPPK1 | c.810C>T p.D270= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs782787665, COSV73260827; called by muse, mutect2, varscan2
- GPR21 | c.585C>A p.I195= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV65378812; called by muse, mutect2, varscan2
- OPN4 | c.339G>A p.A113= | Silent (SNP) | VAF 133/206 reads (65%) | catalogued as rs368882005; called by muse, mutect2, varscan2
- PCDHGA3 | c.810C>T p.D270= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs547334260, COSV53900873; called by muse, mutect2, varscan2
- PRRC1 | c.183G>A p.P61= | Silent (SNP) | VAF 28/326 reads (9%) | catalogued as rs769543226, COSV56987751; called by muse, mutect2
- SRMS | c.846C>T p.H282= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs766255803, COSV53915876; called by muse, mutect2, varscan2
- TLR4 | c.990C>T p.F330= (on ENST00000355622 / NM_138554.5; = p.F290= on NM_003266.4) | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs755087055, COSV62922438; called by muse, mutect2, varscan2
- TRIM72 | c.885G>A p.P295= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs1463338666, COSV59066731, COSV59069005; called by muse, mutect2, varscan2
- UPRT | c.453A>G p.G151= | Silent (SNP) | VAF 70/205 reads (34%) | catalogued as COSV64912121; called by muse, mutect2, varscan2
- ZFAND6 | c.498A>C p.G166= | Silent (SNP) | VAF 68/191 reads (36%) | catalogued as COSV55710848; called by muse, mutect2, varscan2
- C3orf35 | chr3:37417414 C>T | 3'Flank (SNP) | VAF 43/119 reads (36%) | catalogued as rs772073350; called by muse, mutect2, varscan2
- LAMP2 | c.1093+2553T>C | Intron (SNP) | VAF 52/160 reads (33%) | catalogued as COSV52351505; called by muse, mutect2, varscan2
- MIR891B | n.51G>A | RNA (SNP) | VAF 81/208 reads (39%) | called by muse, mutect2, varscan2
